Surgical pathology report (de-identified scan), TCGA case TCGA-AX-A1CR, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site Gynecologic Oncology Group, specimen TCGA-AX-A1CR-01A (Primary Tumor).

[page 1 of 4]
1/9/11

Surgical Pathology Report Temporary Conv

Case: 1-
Collected:
Ordered by:

Page 1 of 4

Patient:
IE
Location:

Clinical Information

PMB, endometrial cancer. Ex lap, TAH/BSO.

Organ Or Tissue

Omentum
Uterus cervix bilateral adnexa

Gross Description

The specimen is received in two parts each labeled with the patient's name.

Part A designated "omentum" was received for frozen section. The specimen consists of a segment of pink red and yellow omental tissue measuring 41.0 x 13.5 x 3.0 cm in greatest dimensions. The specimen reveals multiple areas of tumor deposits and thickening. Representative sections are submitted as follows:

- A1-A4 sections from omentum
- A5 FS 1
- A6 omental tissue for

Part B designated "uterus, cervix, bilateral adnexa" was received for intraoperative consult. The specimen consists of a uterus with attached cervix with attached adnexa. The specimen weighs 211 grams. The uterus measures 10.3 x 4.5 x 4.0 cm. The serosal surface is pink-red, hemorrhagic with possible adhesions in the lower segment. The ectocervix is pink tan, hemorrhagic, and measures 2.5 x 3.5 cm with a 0.8 cm slit-like os. The endocervical canal is pink red with a distinct herringbone appearance and measures 3.0 x 0.8 cm. The endometrial cavity is distorted by the presence of an intramural fibroid in the posterior part and measures approximately 4.0 x 2.5 cm. An exophytic pink tan friable lesion occupies the fundal and upper part of the uterine cavity. The lesion measures approximately 4.0 x 3.5 x 1.5 cm and appears to extend to the middle part of the cavity. The lower uterine segment and cervix are grossly free of tumor. No myometrial invasion is appreciated by gross examination. The left adnexa is comprised of a segment of grossly dilated fallopian tube with attached fimbria measuring 5.0 cm in length and varying in diameter from 0.5 to 1.5 cm. The pale-yellow, pink and focally hemorrhagic ovary measures 1.4 x 2.5 x 1.0 cm. The lateral pole of the ovary reveals a red purple mass of tumor attachment measuring 4.5 x 4.0 x 2.5 cm. The right adnexa is comprised of a segment of fallopian tube with attached fimbria measuring 5.0 cm in length and 0.8 cm in diameter. The proximal part of the tube reveals clear fluid-filled cysts and possible tumor? deposits. The attached ovary is elongated, pink-red and reveals possible tumor deposits on the surface and measures 3.0 x 1.6 x 1.0 cm. Representative sections are submitted as follows:

- B1-B2 anterior and posterior cervix
- B3-B4 anterior and posterior lower uterine segment
- B5-B7 anterior endomyometrium
- B8-B10 posterior endomyometrium
- B11 fibroid
- B12-B13 left tube
- B14-B16 left ovary with tumor
- B17-B18 right tube
- B19-B20 right ovary
- B21 tumor for
- B22 normal tissue for

TCGA-A1CR-01A-PR

[page 2 of 4]
Surgical Pathology Report
Temporary Conv

Case: 1
Collected:
Ordered by:

Page 2 of 4

Patient
IC
Location:

Intra-Operative Consultation

FS1: Omentum:

- Positive for papillary serous adenocarcinoma.
- Tissue has been submitted for _____ and

Uterus, cervix, bilateral adnexa:

- Uterine tumor with no cervical involvement and myometrial invasion grossly.
- One ovary with tumor involvement

Test performed by:

Diagnosis

A. Specimen labeled "Omentum":

- Involvement by papillary serous carcinoma (see comments)

B. Uterus, cervix, bilateral adnexa; hysterectomy and bilateral salpingo-oophorectomy:

Endomyometrium:

- Endometrial adenocarcinoma, mixed endometrioid (approximately 20%; architecturally FIGO grade 1 with grade 3 nuclei) and serous (approximately 80%; grade 3) types (see comments)
- No myometrial invasion
- Tumor is present in the endocervix, with superficial stromal invasion
- Lower uterine segment is not involved by tumor
- No lymphovascular invasion seen
- Cellular leiomyoma, intramural, 4 cm

Cervix:

- Endocervical involvement by papillary serous carcinoma with superficial stromal invasion (see comments)
- Squamous metaplasia and mucous cysts

Serosa:

- Extensive involvement by papillary serous carcinoma, with superficial invasion into the myometrium (see comments)

Left fallopian tube:

- Involvement by papillary serous carcinoma (see comments)

Left Ovary:

- Involvement by papillary serous carcinoma (see comments)

Right fallopian tube:

- Involvement by papillary serous carcinoma (see comments)

Right Ovary:

- Involvement by papillary serous carcinoma (see comments)

[page 3 of 4]
Surgical Pathology Report

Temporary Conv

Case:
Collected:
Ordered by:

Page 3 of 4

Patient
ID
Location:

Electronically signed:

Comments

The case was extensively reviewed at the / and the tumors are felt to be that of an endometrial primary and a separate peritoneal carcinoma and are staged as such.

Type of surgery:	Hysterectomy, bilateral salpingo-oophorectomy
Gross size of tumor:	4.0 x 3.5 x 1.5 cm.
Tumor location:	anterior and posterior fundus
Histologic type:	Mixed endometrioid (20%) and serous (80%) types
Histologic grade (FIGO):	3
Depth of myometrial invasion:	0%
Cervical involvement:	present
Lower uterine segment involvement:	absent
Lymphatic space invasion:	absent
Blood vessel invasion:	absent
Surgical margins:	negative
Other tumor site(s):	Bilateral ovaries and fallopian tubes

OTHER ENDOMETRIAL PATHOLOGY: no

Pelvic washings: not done

LYMPH NODES

Pelvic: Not performed
Para-aortic: Not performed

AJCC (7th Ed, ©2010) Stage: pT2Nx
{EMCA}

Type of surgery:	Hysterectomy, bilateral salpingo-oophorectomy
Major site(s):	
Left ovary:	4.5 x 4.0 x 2.5 cm
Right ovary:	3.0 x 1.6 x 1.0 cm
Omentum:	41.0 x 13.5 x 3.0 cm segment of omentum, extensively involved by tumor
Histologic type:	Papillary Serous Carcinoma
Histologic grade:	3
Lymphatic invasion:	None identified
Blood vessel invasion:	No
Involvement of other organs:	yes
Left fallopian tube:	serosal surface, multifocally
Right fallopian tube:	serosal surface, multifocally

[page 4 of 4]
Diagnosis:	Yes	No

Surgical Pathology Report Temporary Copy

Page 4 of 4

Case:
Collected:
Ordered by: *I*

Patient
IC
Location:

Uterus:	Yes-Serosa, extensive involvement
Other:	no
Additional pathologic findings:	
Endometriosis:	no
Endosalpingiosis:	no
Implants:	no
PELVIC WASHINGS:	Not performed
DIAPHRAGM SMEAR/WASHINGS:	Not performed
LYMPH NODES:	
Pelvic:	Not performed
Periaortic:	Not performed
{Peritoneal CA}	

Source: NCI Genomic Data Commons file 3acf6cbd-a104-4bce-8ee8-cccc5a69e516 (TCGA-AX-A1CR.7623CA86-87C5-43E8-A0A7-25BD9526D1AA.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).